MMRF case MMRF_1312 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/2fa052cc-1555-4d1b-b495-d7444684d534

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.2 years (25,648 days); ISS stage: I; Days to last known disease status: 1,436 days (3.9 years); Days to last follow up: 1,436 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 150 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 200 days; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 341 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -6 (ECOG 0): M Protein 2.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 187 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.6 mg/dL; Immunoglobulin G 43.8 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3.1 µg/mL; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.21 ×10⁹/L; Platelets 232 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 8.8 g/dL; Glucose 7.54 mmol/L.
- Day 78 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.914 mg/dL; Immunoglobulin G 15.4 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 3.47 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 5.94 mmol/L.
- Day 183 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.823 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.15 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 6.22 mmol/L.
- Day 267 (ECOG 0): Lactate Dehydrogenase 3.42 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 6.71 mmol/L.
- Day 340 (ECOG 0): Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 6.49 mmol/L.
- Day 435 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 5.32 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.66 mmol/L.
- Day 519: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.956 mg/dL; Immunoglobulin G 10.5 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 0.8 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.46 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6 g/dL; Glucose 6.44 mmol/L.
- Day 626 (ECOG 0): Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 6.38 mmol/L.
- Day 708 (ECOG 0): Immunoglobulin G 12.9 g/L; Immunoglobulin A 0.97 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.96 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 7.15 mmol/L.
- Day 799 (ECOG 0): Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 887: Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.27 mmol/L.
- Day 983 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.17 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 6.16 mmol/L.
- Day 1,083: Serum Free Immunoglobulin Light Chain, Kappa 4.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.06 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M -0.16 g/L; Beta 2 Microglobulin 1.5 µg/mL; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 5.34 mmol/L.
- Day 1,139 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.97 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M -0.16 g/L; Beta 2 Microglobulin 1.7 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 6.11 mmol/L.
- Day 1,202 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.886 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 8.74 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 1,318 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 3.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.867 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 6.88 mmol/L.
- Day 1,436 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 4.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.37 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -6: Weight: 102 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1312_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -6 days.
- Sample MMRF_1312_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -6 days.
